CCDI case PBCHJX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Heart, mediastinum, and pleura.
https://portal.gdc.cancer.gov/cases/edb4c76f-7e90-45c3-910e-482b37c3ee8b

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 0.4 years (150 days).

Biospecimens (3 samples)
- Sample 0DSMWO: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSMXW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DSMYB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
